Somatic mutation profile of tumor specimen TCGA-DD-AAVU-01A (aliquot TCGA-DD-AAVU-01A-11D-A40R-10) from TCGA case TCGA-DD-AAVU, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 46.2 years (16,889 days).
Specimen TCGA-DD-AAVU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 201dc143-35b1-459d-a596-5a236ad5c07c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAVU-10A (Blood Derived Normal), aliquot TCGA-DD-AAVU-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea4999ff-b60f-4859-9083-8bbe07d3992c

The open-access MAF lists 68 somatic variants for this specimen: 45 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 22, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, 3'UTR 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDE6B | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs121918581, CM950916, COSV99727973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACB | c.6067A>G p.I2023V | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100623084; called by muse, mutect2, varscan2
- ADGRE1 | c.233G>A p.C78Y | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99165481; called by muse, mutect2, varscan2
- AMBRA1 | c.2674G>A p.D892N (on ENST00000458649 / NM_001367468.1; = p.D802N on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100094604; called by muse, mutect2, varscan2
- ANK1 | c.3854T>A p.I1285K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV55895110, COSV99225894; called by muse, mutect2, varscan2
- ASTN2 | c.3436G>T p.V1146F (on ENST00000313400 / NM_001365069.1; = p.V1095F on NM_014010.5) | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV99941062; called by muse, mutect2, varscan2
- ATP8B2 | c.733A>C p.S245R (on ENST00000672630; = p.S212R on NM_001005855.2) | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV100528109; called by muse, mutect2, varscan2
- AXIN1 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 36/44 reads (82%) | catalogued as COSV99250067; called by muse, mutect2, varscan2
- CELSR3 | c.8851T>C p.Y2951H | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV99374153; called by muse, mutect2, varscan2
- COL11A1 | c.4951C>T p.P1651S | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100617337; called by muse, mutect2, varscan2
- COL18A1 | c.1550C>T p.T517I (on ENST00000359759 / NM_130444.3; = p.T282I on NM_030582.4) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100700789; called by muse, mutect2, varscan2
- CPEB3 | c.1240A>T p.S414C | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV99799967; called by muse, mutect2, varscan2
- DGKE | c.634A>G p.K212E | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99401041; called by muse, mutect2, varscan2
- DNAJC16 | c.1238C>G p.T413S | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV101012614; called by muse, mutect2, varscan2
- DRD2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201724929, COSV60762454; called by muse, mutect2, varscan2
- EPHA7 | c.680T>C p.L227S | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100992444; called by muse, mutect2, varscan2
- FGFBP1 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV99469107; called by muse, mutect2, varscan2
- FRAS1 | c.4508A>T p.Y1503F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.183); catalogued as COSV99348168, COSV99353957; called by muse, mutect2, varscan2
- GULP1 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 108/253 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV100770846; called by muse, mutect2, varscan2
- H2AC8 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1299854545, COSV55126329; called by muse, mutect2, varscan2
- IVL | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 45/124 reads (36%) | catalogued as COSV100908205; called by muse, mutect2
- KANK1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs752429506, COSV63217076; called by muse, mutect2, varscan2
- LRRC8C | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as COSV100968320; called by muse, mutect2
- MRS2 | c.466A>G p.N156D | Missense Mutation (SNP) | VAF 93/191 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV99219034; called by muse, mutect2, varscan2
- NCF4 | c.759-3T>A | Splice Region (SNP) | VAF 48/131 reads (37%) | catalogued as COSV99957451; called by muse, mutect2, varscan2
- NPIPB15 | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.005); catalogued as rs2868593; called by muse, mutect2
- NRXN3 | c.3031T>A p.S1011T (on ENST00000335750 / NM_001330195.2; = p.S638T on NM_004796.6) | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100205857; called by muse, mutect2, varscan2
- OBSCN | c.9883T>C p.C3295R | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99481505; called by muse, mutect2, varscan2
- PADI1 | c.1243A>T p.S415C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969190; called by muse, mutect2, varscan2
- PCNX2 | c.3747C>A p.S1249R | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.212); catalogued as COSV99268513; called by muse, mutect2, varscan2
- PCP2 | c.152A>T p.Q51L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99657256; called by muse, mutect2, varscan2
- PIDD1 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs554590814, COSV100758697; called by muse, mutect2, varscan2
- RPGRIP1 | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV99251351; called by muse, mutect2, varscan2
- RPS7 | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 178/351 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs922826398, COSV100513984; called by muse, mutect2, varscan2
- SERPINA5 | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV100291708; called by muse, mutect2, varscan2
- SLIT2 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs80248215, COSV56561255; called by muse, mutect2, varscan2
- SPEN | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs1483388473, COSV101005402; called by muse, mutect2, varscan2
- TBX18 | c.1510T>A p.S504T | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100858539; called by muse, mutect2, varscan2
- TRABD2A | c.1419C>G p.H473Q (on ENST00000409520 / NM_001277053.2; = p.H424Q on NM_001080824.3) | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV99407569; called by muse, mutect2, varscan2
- TTN | c.70174G>C p.D23392H (on ENST00000591111; = p.D15968H on NM_003319.4) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | PolyPhen probably damaging (0.999); catalogued as COSV100620376; called by muse, mutect2, varscan2
- ZNF608 | c.389T>A p.I130N | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.629); catalogued as COSV100102061; called by muse, mutect2, varscan2
- ALB | c.482+5_482+8del p.X161_splice | Splice Site (DEL) | VAF 20/55 reads (36%) | called by pindel, varscan2
- CENPC | c.1260dup p.Q421Tfs*8 | Frame Shift Ins (INS) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- PCDH7 | c.71-1G>C p.X24_splice (on ENST00000509759; = p.X748_splice on NM_032457.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- RIMS2 | c.2693del p.D898Afs*8 (on ENST00000666250 / NM_001348490.2; = p.D706Afs*8 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 124/204 reads (61%) | called by mutect2, pindel, varscan2
- ARHGAP11A | c.1158A>G p.V386= | Silent (SNP) | VAF 69/149 reads (46%) | catalogued as rs764281924, COSV100853290; called by muse, mutect2, varscan2
- BACH2 | c.648C>T p.T216= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs1315295818, COSV100000170; called by muse, mutect2, varscan2
- BARD1 | c.343C>T p.L115= | Silent (SNP) | VAF 50/125 reads (40%) | catalogued as COSV99639186; called by muse, mutect2, varscan2
- CDH9 | c.1815G>T p.L605= | Silent (SNP) | VAF 92/197 reads (47%) | catalogued as COSV50396597; called by muse, mutect2, varscan2
- CHD8 | c.1320G>A p.S440= (on ENST00000646647 / NM_001170629.2; = p.S161= on NM_020920.4) | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs898418482, COSV67872764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCC | c.1587G>C p.G529= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV100501388; called by muse, mutect2, varscan2
- DEFB123 | c.87T>C p.Y29= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as rs377702716, COSV66233123; called by muse, mutect2, varscan2
- DNAH2 | c.9966A>G p.G3322= | Silent (SNP) | VAF 25/29 reads (86%) | catalogued as rs375895814, COSV66727819; called by muse, mutect2, varscan2
- IGDCC4 | c.906G>A p.A302= | Silent (SNP) | VAF 65/120 reads (54%) | catalogued as COSV100733010; called by muse, mutect2, varscan2
- IZUMO1R | c.363T>C p.N121= (on ENST00000440961; = p.N128= on NM_001199206.3) | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as COSV100126899, COSV60623053; called by muse, mutect2, varscan2
- NINL | c.2004G>A p.E668= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV99625709; called by muse, mutect2, varscan2
- OLFM2 | c.321C>T p.L107= | Silent (SNP) | VAF 59/114 reads (52%) | catalogued as COSV99321896; called by muse, mutect2, varscan2
- PCDHB7 | c.2151G>C p.A717= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as COSV99176899, COSV99177136, COSV99177482; called by muse, mutect2, varscan2
- PTBP1 | c.669G>A p.Q223= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV100608865; called by muse, mutect2, varscan2
- SCRN2 | c.1065G>A p.R355= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as rs1257374752, COSV99274192; called by muse, mutect2, varscan2
- SERPINF1 | c.663T>C p.F221= | Silent (SNP) | VAF 34/42 reads (81%) | catalogued as COSV99628886; called by muse, mutect2
- SLC44A1 | c.1224A>C p.A408= | Silent (SNP) | VAF 78/85 reads (92%) | catalogued as COSV100570543; called by muse, mutect2, varscan2
- SUPT20HL1 | c.885C>T p.G295= | Silent (SNP) | VAF 214/244 reads (88%) | catalogued as rs368897164; called by muse, mutect2, varscan2
- TARBP2 | c.855C>G p.G285= (on ENST00000266987 / NM_134323.2; = p.G264= on NM_004178.4) | Silent (SNP) | VAF 21/25 reads (84%) | catalogued as COSV99908585; called by muse, mutect2, varscan2
- TLN2 | c.1443G>T p.G481= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as COSV100169526; called by muse, mutect2, varscan2
- TNFRSF11A | c.633G>A p.L211= | Silent (SNP) | VAF 72/154 reads (47%) | catalogued as COSV99500358; called by muse, mutect2, varscan2
- ZNF765 | c.1113A>G p.T371= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as rs754007672, COSV101125515; called by muse, mutect2, varscan2
- SNX18 | c.*28C>T | 3'UTR (SNP) | VAF 112/255 reads (44%) | catalogued as COSV100543600; called by muse, mutect2, varscan2
